Somatic mutation profile of tumor specimen ALCH-B1YF-TTR1-A (aliquot ALCH-B1YF-TTR1-A-12-0-D-A80E-36) from ALCHEMIST case ALCH-B1YF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.1 years (23,786 days).
Specimen ALCH-B1YF-TTR1-A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07250db2-0784-4121-a0dc-ac6ec1c7a630.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1YF-NB1-A (Blood Derived Normal), aliquot ALCH-B1YF-NB1-A-1-0-D-A772-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfc4605e-0952-441c-9d76-4ff7a4bb838c

The open-access MAF lists 324 somatic variants for this specimen: 219 protein-altering or splice-affecting, 71 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 179, Silent 71, Intron 18, Nonsense Mutation 17, Splice Site 8, Frame Shift Del 8, 3'UTR 8, 5'Flank 5, Splice Region 3, Frame Shift Ins 3, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 553/868 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.653T>A p.V218E | Missense Mutation (SNP) | VAF 128/159 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52690974, COSV52712839, COSV52761003; called by muse, mutect2, varscan2
- ABCB11 | c.3957del p.I1320Sfs*60 | Frame Shift Del (DEL) | VAF 58/228 reads (25%) | catalogued as rs1559173213; called by mutect2, pindel, varscan2
- ALG14 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs1345134392; called by muse, mutect2, varscan2
- ANKRD30B | c.2751G>T p.E917D | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.503); catalogued as COSV57705053; called by muse, mutect2, varscan2
- BANK1 | c.119G>T p.W40L | Missense Mutation (SNP) | VAF 73/105 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59844662; called by muse, mutect2, varscan2
- CABP4 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1361811313; called by muse, mutect2, varscan2
- CACNA1S | c.259-1G>T p.X87_splice | Splice Site (SNP) | VAF 32/166 reads (19%) | catalogued as COSV62944933; called by muse, mutect2, varscan2
- CBX8 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53935593; called by muse, mutect2, varscan2
- CFAP94 | c.1648A>G p.I550V (on ENST00000320267 / NM_001352064.2; = p.I556V on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs985141564; called by muse, mutect2, varscan2
- CIT | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 196/498 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs369209873, COSV55881092; called by muse, mutect2, varscan2
- CNDP1 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 126/207 reads (61%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.595); catalogued as COSV62593284; called by muse, mutect2, varscan2
- CPNE4 | c.1047C>A p.C349* | Nonsense Mutation (SNP) | VAF 196/281 reads (70%) | catalogued as COSV70198380; called by muse, mutect2, varscan2
- DCAF4L2 | c.273A>T p.Q91H | Missense Mutation (SNP) | VAF 110/143 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV100151192; called by muse, mutect2, varscan2
- DCDC1 | c.1290G>T p.K430N | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV60836325; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs754135731; called by mutect2, varscan2*
- DICER1 | c.3359A>G p.N1120S | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1555369701, COSV58624940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH10 | c.11389G>A p.E3797K (on ENST00000409039; = p.E3736K on NM_207437.3) | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.125); catalogued as rs1214736953; called by muse, mutect2, varscan2
- FASN | c.304G>T p.G102* | Nonsense Mutation (SNP) | VAF 25/134 reads (19%) | catalogued as COSV60755699; called by muse, mutect2, varscan2
- FAT3 | c.7337G>T p.S2446I | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV53160442; called by muse, mutect2, varscan2
- FBXO11 | c.1625C>A p.S542Y (on ENST00000403359 / NM_001190274.2; = p.S458Y on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV57024529; called by muse, mutect2, varscan2
- FRAS1 | c.5822G>A p.R1941H | Missense Mutation (SNP) | VAF 89/177 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as rs771945455; called by muse, mutect2, varscan2
- FSIP2 | c.8958C>A p.N2986K | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV58077483; called by muse, mutect2, varscan2
- GABRA2 | c.1019G>C p.R340T | Missense Mutation (SNP) | VAF 168/341 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62917407; called by muse, mutect2, varscan2
- GLI2 | c.2593A>T p.T865S (on ENST00000361492 / NM_001374353.1; = p.T882S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs1332140763; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIA2 | c.908C>A p.A303D | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV99645294; called by muse, mutect2, varscan2
- IGKV2-28 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as rs755410043; called by mutect2, varscan2
- IL12RB1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 113/140 reads (81%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs865858530, COSV59096650; called by muse, mutect2, varscan2
- IL1RAPL1 | c.740C>A p.P247H | Missense Mutation (SNP) | VAF 185/692 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56246658; called by muse, mutect2, varscan2
- INSYN2B | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs183865899, COSV56955260; called by muse, mutect2, varscan2
- ISOC1 | c.140A>G p.Y47C | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.157); catalogued as rs1323246175; called by muse, mutect2, varscan2
- KCNAB3 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1388525184; called by muse, mutect2, varscan2
- KCNB2 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101578707, COSV73048983; called by muse, mutect2, varscan2
- LARGE2 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs576172696, COSV99139660; called by muse, mutect2, varscan2
- LRRTM4 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 43/115 reads (37%) | catalogued as COSV69139072; called by muse, mutect2, varscan2
- MC4R | c.788T>C p.L263P | Missense Mutation (SNP) | VAF 66/302 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1210126795; called by muse, mutect2, varscan2
- MYH6 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 83/232 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV62451008; called by muse, mutect2, varscan2
- MYO1B | c.2875G>T p.V959F (on ENST00000304164; = p.V901F on NM_012223.5) | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1471134167; called by muse, mutect2, varscan2
- NCAPD3 | c.1794G>C p.Q598H | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101599380; called by muse, mutect2, varscan2
- NEU2 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 17/121 reads (14%) | catalogued as rs934377406; called by muse, mutect2, varscan2
- NFAT5 | c.1641_1643del p.X547_splice | Splice Site (DEL) | VAF 30/114 reads (26%) | catalogued as rs1336789582; called by pindel, varscan2
- OR1M1 | c.476A>C p.H159P | Missense Mutation (SNP) | VAF 69/79 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs748541045; called by muse, mutect2, varscan2
- OR2AK2 | c.818C>A p.A273E | Missense Mutation (SNP) | VAF 50/60 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV63549457; called by muse, varscan2
- OTOGL | c.1978C>T p.P660S (on ENST00000547103; = p.P651S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/419 reads (26%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.887); catalogued as COSV72006654, COSV72006688; called by muse, mutect2, varscan2
- PAPPA2 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 72/124 reads (58%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.329); catalogued as COSV62777606; called by muse, mutect2, varscan2
- PCDH7 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100687862; called by muse, mutect2, varscan2
- PCDHGB5 | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 58/171 reads (34%) | catalogued as rs1344845350, COSV53973945; called by muse, mutect2, varscan2
- PDZRN4 | c.2082C>A p.D694E (on ENST00000402685 / NM_001164595.2; = p.D436E on NM_013377.4) | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV54210334; called by muse, mutect2, varscan2
- PRKAG3 | c.435G>T p.W145C | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs748763400, COSV52102608; called by muse, mutect2, varscan2
- PRSS1 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 261/565 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs201775810, COSV61191219; called by muse, mutect2, varscan2
- PTK6 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs61736392; called by muse, mutect2
- RGS1 | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 121/218 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357289806; called by muse, mutect2, varscan2
- RGS7BP | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs771054378; called by muse, varscan2
- RHOXF1 | c.16G>T p.V6F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.057); catalogued as rs931167506, COSV99483843; called by muse, mutect2, varscan2
- RIF1 | c.1651C>T p.L551F | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1466188708; called by muse, mutect2, varscan2
- RIN2 | c.428A>T p.H143L (on ENST00000255006 / NM_001242581.1; = p.H94L on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs1245028694; called by muse, mutect2
- SEMA3C | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 145/273 reads (53%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as rs529243342, COSV54850790; called by muse, mutect2, varscan2
- SERHL | n.432G>A | Splice Region (SNP) | VAF 20/83 reads (24%) | catalogued as rs1267233485; called by muse, varscan2
- SIRT5 | c.661G>T p.V221L | Missense Mutation (SNP) | VAF 79/153 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs150816932, COSV100702846; called by muse, mutect2, varscan2
- SPTA1 | c.2588-1G>A p.X863_splice | Splice Site (SNP) | VAF 63/219 reads (29%) | catalogued as COSV63753653; called by muse, mutect2, varscan2
- STAG2 | c.3034C>T p.R1012* | Nonsense Mutation (SNP) | VAF 45/138 reads (33%) | catalogued as COSV54350913; called by muse, mutect2, varscan2
- STK11 | c.762del p.F255Sfs*32 | Frame Shift Del (DEL) | VAF 24/36 reads (67%) | catalogued as CM981869, COSV58825310; called by mutect2, pindel, varscan2
- TAS2R30 | c.298A>T p.T100S | Missense Mutation (SNP) | VAF 218/299 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs748299614; called by muse, mutect2, varscan2
- TENM1 | c.2975C>A p.P992Q | Missense Mutation (SNP) | VAF 53/249 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV100949733; called by muse, mutect2, varscan2
- TENM3 | c.7082C>G p.A2361G | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV69306135; called by muse, mutect2, varscan2
- TINAG | c.912C>A p.H304Q | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as rs751188992, COSV99449100, COSV99451191; called by muse, mutect2, varscan2
- TNFSF15 | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV65010605, COSV65010926; called by muse, mutect2, varscan2
- TSHZ3 | c.2471C>T p.T824M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs770738477, COSV53664420; called by muse, mutect2, varscan2
- ZFHX4 | c.8453A>G p.E2818G | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50800112; called by muse, mutect2, varscan2
- ZFYVE28 | c.1409G>A p.G470E | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.026); catalogued as rs1433494983; called by muse, mutect2, varscan2
- ZNF804B | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 119/251 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60822516; called by muse, mutect2, varscan2
- ABCD2 | c.1237-2A>T p.X413_splice | Splice Site (SNP) | VAF 26/78 reads (33%) | called by muse, mutect2, varscan2
- AC008397.2 | c.1997A>G p.E666G | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACACB | c.193C>T p.H65Y | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADGRV1 | c.2318G>T p.G773V | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALKAL2 | c.208C>G p.R70G | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ANK2 | c.11422G>A p.E3808K | Missense Mutation (SNP) | VAF 164/258 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ANKRD20A4P | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.18); PolyPhen benign (0.255); called by mutect2, varscan2
- APLF | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARGLU1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 252/318 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ARHGAP32 | c.4492C>T p.P1498S (on ENST00000310343 / NM_001378025.1; = p.P1149S on NM_014715.4) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP5 | c.4384G>C p.A1462P (on ENST00000345122 / NM_001030055.2; = p.A1461P on NM_001173.3) | Missense Mutation (SNP) | VAF 42/516 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2
- ARHGEF33 | c.866A>T p.K289M | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AVPR1A | c.583A>G p.N195D | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BIN2 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 91/178 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BNC2 | c.1229C>A p.P410Q | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BRINP2 | c.1701G>C p.M567I | Missense Mutation (SNP) | VAF 99/162 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC168 | c.21057T>A p.C7019* | Nonsense Mutation (SNP) | VAF 38/51 reads (75%) | called by muse, mutect2, varscan2
- CD200R1L | c.261G>T p.E87D | Missense Mutation (SNP) | VAF 342/490 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CDC42BPA | c.2449T>A p.W817R | Missense Mutation (SNP) | VAF 281/343 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDC45 | c.240T>G p.N80K | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CDCA3 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CFHR1 | c.836C>A p.A279E | Missense Mutation (SNP) | VAF 82/426 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- CLEC2B | c.392C>G p.A131G | Missense Mutation (SNP) | VAF 164/240 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- CLEC2B | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 165/240 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CNGB3 | c.1933C>T p.L645F | Missense Mutation (SNP) | VAF 82/1230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- COL11A2 | c.4393G>A p.G1465R (on ENST00000341947 / NM_080680.3; = p.G1358R on NM_080679.2) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPNE4 | c.1048C>A p.Q350K | Missense Mutation (SNP) | VAF 196/284 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.10024C>A p.P3342T (on ENST00000297405 / NM_001363185.1; = p.P3173T on NM_052900.3) | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- CTNND2 | c.2384G>A p.C795Y | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DCAF17 | c.1267-5dup | Splice Region (INS) | VAF 38/158 reads (24%) | called by mutect2, pindel, varscan2
- DDHD1 | c.1241T>G p.L414* (on ENST00000323669; = p.L611* on NM_030637.3) | Nonsense Mutation (SNP) | VAF 56/166 reads (34%) | called by muse, mutect2, varscan2
- DOCK11 | c.2928G>T p.L976F | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DOP1B | c.3131A>T p.E1044V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- DST | c.4197+1G>C p.X1399_splice (on ENST00000361203 / NM_001374722.1; = p.X1073_splice on NM_001723.6) | Splice Site (SNP) | VAF 198/400 reads (50%) | called by muse, mutect2, varscan2
- DTHD1 | c.1120C>T p.H374Y (on ENST00000456874; = p.H209Y on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ECEL1 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- EZH1 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM120A | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 52/79 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FAM53B | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- FNDC8 | c.737T>C p.M246T | Missense Mutation (SNP) | VAF 55/260 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GCC1 | c.1830del p.L611Wfs*29 | Frame Shift Del (DEL) | VAF 34/180 reads (19%) | called by mutect2, pindel, varscan2
- GH2 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2, varscan2
- GOLGA4 | c.5263G>T p.V1755L | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOPC | c.994G>T p.V332F | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRIK5 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HDGF | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 178/331 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HELZ2 | c.570+5G>A | Splice Region (SNP) | VAF 44/190 reads (23%) | called by muse, mutect2, varscan2
- HGF | c.410A>T p.K137M | Missense Mutation (SNP) | VAF 145/493 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HMCN1 | c.11564T>A p.L3855H | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMCN2 | c.5194G>T p.V1732L | Missense Mutation (SNP) | VAF 85/125 reads (68%) | SIFT tolerated (0.39); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HS3ST4 | c.341C>A p.P114H | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- IGHV3-20 | c.334T>A p.L112M | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.175G>C p.A59P | Missense Mutation (SNP) | VAF 155/511 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- IGKV3D-7 | c.56del p.P19Qfs*8 | Frame Shift Del (DEL) | VAF 115/445 reads (26%) | called by mutect2, pindel, varscan2
- IL21R | c.242G>C p.C81S | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL6ST | c.1144G>T p.V382F | Missense Mutation (SNP) | VAF 51/271 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ING1 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ITGA2 | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 200/402 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCND1 | c.1284G>C p.Q428H | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- KDR | c.3194C>A p.A1065D | Missense Mutation (SNP) | VAF 209/326 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KEAP1 | c.1116del p.L373Cfs*27 | Frame Shift Del (DEL) | VAF 11/17 reads (65%) | called by mutect2, pindel, varscan2
- KLHL13 | c.1033C>A p.L345I | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KRT37 | c.663G>T p.K221N | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- KRTAP10-5 | c.31A>T p.S11C | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- LAMA4 | c.3763G>A p.D1255N (on ENST00000230538 / NM_001105206.3; = p.D1248N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LAMA4 | c.2959G>T p.V987L (on ENST00000230538 / NM_001105206.3; = p.V980L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- LRP2 | c.11593G>C p.D3865H | Missense Mutation (SNP) | VAF 136/611 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2
- LRP2 | c.9396T>A p.S3132R | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRIQ3 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.072); called by muse, mutect2
- MALRD1 | c.6317A>G p.K2106R | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.184); called by muse, varscan2
- MCPH1 | c.929T>A p.V310E | Missense Mutation (SNP) | VAF 125/183 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- MNDA | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MTCL1 | c.1729G>C p.E577Q (on ENST00000306329 / NM_001378206.1; = p.E217Q on NM_015210.4) | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTNR1A | c.142G>C p.V48L | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- MYO1F | c.2789T>C p.M930T | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYPN | c.2921del p.P974Qfs*21 | Frame Shift Del (DEL) | VAF 96/279 reads (34%) | called by mutect2, pindel, varscan2
- NCR3LG1 | c.29G>T p.C10F | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- NDUFA10 | c.805-1G>A p.X269_splice | Splice Site (SNP) | VAF 111/420 reads (26%) | called by muse, mutect2, varscan2
- NDUFAF5 | c.788del p.E263Gfs*44 | Frame Shift Del (DEL) | VAF 173/524 reads (33%) | called by mutect2, pindel, varscan2
- NEXMIF | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 56/198 reads (28%) | called by muse, mutect2, varscan2
- NHSL1 | c.2915C>G p.S972C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- NIPAL4 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- NLRP14 | c.2420G>T p.C807F | Missense Mutation (SNP) | VAF 195/372 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH2 | c.7054G>T p.A2352S | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.86); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NOTCH4 | c.2038G>C p.D680H | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- NUTM2A | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- NXPH3 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2G6 | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 94/141 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OR51G1 | c.487T>C p.F163L | Missense Mutation (SNP) | VAF 98/292 reads (34%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- OR56B1 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 77/195 reads (39%) | called by muse, mutect2, varscan2
- OR8G2P | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PADI4 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCCA | c.1944A>C p.K648N | Missense Mutation (SNP) | VAF 250/322 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PCDH15 | c.4520C>A p.P1507H (on ENST00000644397 / NM_001354429.2; = p.L1468M on NM_001142770.3) | Missense Mutation (SNP) | VAF 88/175 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PDZRN4 | c.2083C>A p.Q695K (on ENST00000402685 / NM_001164595.2; = p.Q437K on NM_013377.4) | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PLEC | c.2547C>G p.C849W (on ENST00000322810 / NM_201380.4; = p.C739W on NM_000445.5) | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PLEKHM3 | c.1977C>A p.F659L | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- PLOD3 | c.1114A>T p.R372W | Missense Mutation (SNP) | VAF 93/164 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POLQ | c.1324dup p.A442Gfs*34 | Frame Shift Ins (INS) | VAF 174/334 reads (52%) | called by mutect2, pindel, varscan2
- PTPN3 | c.1682T>G p.L561* | Nonsense Mutation (SNP) | VAF 70/116 reads (60%) | called by muse, mutect2, varscan2
- RAB33A | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- RAD54B | c.2570A>T p.H857L | Missense Mutation (SNP) | VAF 92/793 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RAD54B | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 85/535 reads (16%) | called by muse, mutect2, varscan2
- RAD54L | c.2075C>A p.P692Q | Missense Mutation (SNP) | VAF 193/251 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RANBP2 | c.4708G>A p.D1570N | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM22 | c.547C>A p.H183N | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- REELD1 | c.577G>C p.V193L | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF170 | c.244T>C p.Y82H | Missense Mutation (SNP) | VAF 166/236 reads (70%) | SIFT tolerated (0.44); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RTKN2 | c.1113G>T p.Q371H | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.13784T>G p.V4595G | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- SAMD9 | c.2530dup p.S844Kfs*23 | Frame Shift Ins (INS) | VAF 38/90 reads (42%) | called by mutect2, varscan2
- SATL1 | c.716C>A p.P239Q (on ENST00000395409; = p.P426Q on NM_001012980.2) | Missense Mutation (SNP) | VAF 77/125 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SC5D | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SEC23IP | c.1261C>G p.P421A | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SFMBT1 | c.2464A>G p.I822V | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SH3D19 | c.803-1G>T p.X268_splice | Splice Site (SNP) | VAF 52/227 reads (23%) | called by muse, mutect2, varscan2
- SH3RF2 | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- SIM1 | c.538T>A p.Y180N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SNX25 | c.1403C>A p.A468E | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- SOGA3 | c.2057G>C p.G686A | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SSX1 | c.200T>A p.L67H | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- STOX1 | c.2286dup p.G763Wfs*14 | Frame Shift Ins (INS) | VAF 83/676 reads (12%) | called by mutect2, pindel, varscan2
- SWAP70 | c.1165A>C p.T389P | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SYCP1 | c.2092G>T p.E698* | Nonsense Mutation (SNP) | VAF 68/92 reads (74%) | called by muse, mutect2, varscan2
- TAAR6 | c.749C>A p.A250D | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TGFBR3 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 74/291 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THAP4 | c.823G>T p.G275* | Nonsense Mutation (SNP) | VAF 69/166 reads (42%) | called by muse, mutect2, varscan2
- TMEM200A | c.724C>G p.L242V | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TMEM265 | c.283del p.L95Cfs*36 | Frame Shift Del (DEL) | VAF 40/104 reads (38%) | called by mutect2, pindel, varscan2
- TRHDE | c.2553T>A p.N851K | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- TRIM21 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TRIM49C | c.971C>A p.T324K | Missense Mutation (SNP) | VAF 81/353 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM54 | c.586G>T p.E196* (on ENST00000380075 / NM_187841.3; = p.E238* on NM_032546.4) | Nonsense Mutation (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- TTK | c.908G>T p.R303I | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TTLL9 | c.198A>T p.E66D | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- TTN | c.79627A>T p.S26543C (on ENST00000591111; = p.S19119C on NM_003319.4) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- UNC79 | c.1043G>T p.R348M (on ENST00000393151 / NM_001346218.2; = p.R171M on NM_020818.5) | Missense Mutation (SNP) | VAF 122/244 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2
- VPS54 | c.1256A>G p.N419S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- XIRP2 | c.5506G>C p.E1836Q (on ENST00000628543; = p.E2011Q on NM_152381.6) | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- XRCC6 | c.1405C>T p.L469F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZNF208 | c.715A>T p.S239C | Missense Mutation (SNP) | VAF 119/160 reads (74%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZNF326 | c.1603A>T p.I535L | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF33A | c.2212C>T p.H738Y (on ENST00000458705 / NM_006974.3; = p.H739Y on NM_006954.2) | Missense Mutation (SNP) | VAF 128/159 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZNF454 | c.104A>T p.Q35L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF649 | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 155/195 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ZNF671 | c.266-1G>C p.X89_splice | Splice Site (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- ZNF804A | c.3091G>T p.E1031* | Nonsense Mutation (SNP) | VAF 109/207 reads (53%) | called by muse, mutect2, varscan2
- ZUP1 | c.610A>T p.N204Y | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- ABCB5 | c.2736G>T p.S912= (on ENST00000404938 / NM_001163941.2; = p.S467= on NM_178559.6) | Silent (SNP) | VAF 54/124 reads (44%) | catalogued as COSV51707168, COSV51708453; called by muse, mutect2, varscan2
- ABCC1 | c.1089C>T p.G363= | Silent (SNP) | VAF 90/154 reads (58%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.1539C>A p.V513= | Silent (SNP) | VAF 204/280 reads (73%) | called by muse, mutect2, varscan2
- ADGRL3 | c.294C>A p.V98= (on ENST00000506720 / NM_001322402.2; = p.V30= on NM_015236.6) | Silent (SNP) | VAF 16/149 reads (11%) | called by muse, mutect2, varscan2
- ALX1 | c.192C>T p.R64= | Silent (SNP) | VAF 36/150 reads (24%) | called by muse, mutect2, varscan2
- ANKLE2 | c.2721C>T p.P907= | Silent (SNP) | VAF 85/167 reads (51%) | catalogued as rs199684875; called by muse, mutect2, varscan2
- ARHGAP6 | c.2709C>A p.G903= (on ENST00000337414 / NM_013427.3; = p.G700= on NM_013423.3) | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- BRK1 | c.57G>A p.R19= | Silent (SNP) | VAF 11/155 reads (7%) | catalogued as rs761339201; called by muse, mutect2
- BRPF1 | c.2343A>T p.P781= | Silent (SNP) | VAF 47/53 reads (89%) | called by muse, mutect2, varscan2
- C1QTNF4 | c.648G>T p.A216= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100209355; called by muse, mutect2
- CACNG6 | c.222C>T p.A74= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV99403423; called by muse, mutect2
- CCDC74A | c.159G>A p.L53= | Silent (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- CCDC88C | c.3486G>T p.A1162= | Silent (SNP) | VAF 39/218 reads (18%) | catalogued as rs554400203, COSV101106313; called by muse, mutect2, varscan2
- CDH18 | c.2062C>A p.R688= | Silent (SNP) | VAF 47/166 reads (28%) | catalogued as rs1241315753, COSV56935440, COSV99937677; called by muse, mutect2, varscan2
- CHD5 | c.5787C>G p.P1929= | Silent (SNP) | VAF 37/45 reads (82%) | called by muse, mutect2, varscan2
- CSMD3 | c.6126T>A p.L2042= (on ENST00000297405 / NM_001363185.1; = p.L1938= on NM_052900.3) | Silent (SNP) | VAF 50/87 reads (57%) | called by muse, mutect2, varscan2
- DACH2 | c.408C>T p.A136= | Silent (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- DDHD1 | c.489T>C p.Y163= (on ENST00000323669; = p.Y360= on NM_030637.3) | Silent (SNP) | VAF 134/355 reads (38%) | catalogued as rs749268024; called by muse, mutect2, varscan2
- DHRS2 | c.393G>A p.L131= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
- DMBT1 | c.7149C>T p.D2383= (on ENST00000338354 / NM_001377530.1; = p.D1626= on NM_004406.3) | Silent (SNP) | VAF 34/159 reads (21%) | catalogued as rs749231034, COSV57533611; called by muse, mutect2, varscan2
- DNAJC11 | c.1476G>A p.L492= | Silent (SNP) | VAF 36/146 reads (25%) | called by muse, mutect2, varscan2
- EMD | c.675C>A p.L225= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- ESRRB | c.348C>A p.G116= | Silent (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
- FANCM | c.5412G>A p.G1804= | Silent (SNP) | VAF 57/210 reads (27%) | called by muse, mutect2, varscan2
- HCLS1 | c.252A>T p.G84= | Silent (SNP) | VAF 154/187 reads (82%) | called by muse, mutect2, varscan2
- HOXB1 | c.759C>T p.N253= | Silent (SNP) | VAF 22/41 reads (54%) | called by muse, varscan2
- HYDIN | c.5766G>A p.L1922= | Silent (SNP) | VAF 99/220 reads (45%) | called by muse, mutect2, varscan2
- IGFBP1 | c.141G>T p.S47= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV51875526; called by muse, mutect2, varscan2
- IL21R | c.1185G>A p.E395= | Silent (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- IL6ST | c.1143A>T p.T381= | Silent (SNP) | VAF 48/267 reads (18%) | called by muse, mutect2, varscan2
- KRT82 | c.630G>A p.E210= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as COSV57786059; called by muse, mutect2, varscan2
- KRTAP10-4 | c.96C>T p.C32= | Silent (SNP) | VAF 52/136 reads (38%) | called by muse, mutect2, varscan2
- MED24 | c.1656C>T p.T552= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV62418758; called by mutect2, varscan2
- MFAP3L | c.957G>C p.V319= | Silent (SNP) | VAF 35/212 reads (17%) | called by muse, mutect2, varscan2
- MICAL3 | c.2886G>T p.P962= | Silent (SNP) | VAF 70/222 reads (32%) | called by muse, varscan2
- MKI67 | c.3141G>T p.T1047= | Silent (SNP) | VAF 54/153 reads (35%) | called by muse, mutect2, varscan2
- MYH4 | c.2202C>T p.I734= | Silent (SNP) | VAF 100/254 reads (39%) | catalogued as COSV55115560; called by muse, mutect2, varscan2
- NKX2-1 | c.258C>T p.Y86= | Silent (SNP) | VAF 38/175 reads (22%) | catalogued as rs1292946504; called by muse, mutect2, varscan2
- NLRP10 | c.1557C>T p.D519= | Silent (SNP) | VAF 93/237 reads (39%) | called by muse, mutect2, varscan2
- NOTCH1 | c.2916C>T p.P972= | Silent (SNP) | VAF 40/219 reads (18%) | catalogued as rs754724517; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUP62CL | c.81C>A p.T27= | Silent (SNP) | VAF 65/258 reads (25%) | catalogued as COSV65235256; called by muse, mutect2, varscan2
- OR10Q1 | c.561T>A p.P187= | Silent (SNP) | VAF 9/233 reads (4%) | called by muse, mutect2
- OR2AK2 | c.735G>T p.L245= | Silent (SNP) | VAF 98/135 reads (73%) | called by muse, varscan2
- PCBP2 | c.477C>T p.V159= | Silent (SNP) | VAF 60/223 reads (27%) | called by muse, mutect2, varscan2
- PCDHB14 | c.2088G>T p.S696= | Silent (SNP) | VAF 71/205 reads (35%) | catalogued as COSV53391324; called by muse, mutect2, varscan2
- PCDHGA11 | c.2268C>T p.H756= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV53908516, COSV99535867; called by muse, mutect2, varscan2
- PHF2 | c.264C>T p.L88= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as rs1053913339, COSV63680700; called by muse, mutect2, varscan2
- PLEKHF2 | c.147G>A p.K49= | Silent (SNP) | VAF 68/1373 reads (5%) | called by muse, mutect2
- POF1B | c.1593A>T p.I531= | Silent (SNP) | VAF 57/280 reads (20%) | called by muse, mutect2, varscan2
- PRR35 | c.1125G>A p.G375= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1443848544; called by muse, mutect2, varscan2
- PTK7 | c.1926C>T p.H642= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs1210889322; called by muse, mutect2, varscan2
- RARS2 | c.1515C>T p.F505= | Silent (SNP) | VAF 143/458 reads (31%) | catalogued as rs530229446, COSV65759989; called by muse, mutect2, varscan2
- RDH16 | c.615A>G p.E205= | Silent (SNP) | VAF 39/91 reads (43%) | called by muse, mutect2, varscan2
- SASS6 | c.156G>A p.T52= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs1333901750; called by muse, mutect2, varscan2
- SEC31B | c.3456G>A p.A1152= | Silent (SNP) | VAF 33/257 reads (13%) | catalogued as rs568725038; called by muse, mutect2, varscan2
- SH3RF2 | c.1197G>T p.L399= | Silent (SNP) | VAF 58/171 reads (34%) | called by muse, mutect2, varscan2
- SOWAHC | c.96C>T p.A32= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, varscan2
- SPOP | c.627G>A p.Q209= | Silent (SNP) | VAF 37/169 reads (22%) | called by muse, mutect2, varscan2
- SPTA1 | c.3726G>T p.L1242= | Silent (SNP) | VAF 37/137 reads (27%) | catalogued as rs976782932, COSV100934618, COSV100935664; called by muse, mutect2, varscan2
- SSX1 | c.201C>A p.L67= | Silent (SNP) | VAF 56/267 reads (21%) | catalogued as COSV100976344; called by muse, mutect2, varscan2
- TAS2R7 | c.411C>T p.C137= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as rs375435543; called by muse, mutect2
- TEX13C | c.1527A>T p.L509= | Silent (SNP) | VAF 34/140 reads (24%) | called by muse, varscan2
- TIMD4 | c.519C>A p.T173= | Silent (SNP) | VAF 134/366 reads (37%) | called by muse, mutect2, varscan2
- TOM1 | c.801G>C p.R267= | Silent (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- TRIM5 | c.303A>G p.K101= | Silent (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- TTC6 | c.2325G>C p.V775= | Silent (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- TYR | c.879C>A p.P293= | Silent (SNP) | VAF 40/210 reads (19%) | catalogued as COSV54486952; called by muse, mutect2, varscan2
- VARS2 | c.646A>C p.R216= | Silent (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- XKR4 | c.1635C>A p.T545= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs779891836; called by muse, mutect2, varscan2
- ZIC1 | c.1281C>T p.S427= | Silent (SNP) | VAF 86/121 reads (71%) | catalogued as rs1200372716, COSV51556115; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF860 | c.861G>A p.K287= | Silent (SNP) | VAF 162/215 reads (75%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500078 G>A | 5'Flank (SNP) | VAF 57/298 reads (19%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500079 A>T | 5'Flank (SNP) | VAF 57/298 reads (19%) | called by muse, mutect2, varscan2
- AP001267.5 | c.-799+33219C>T | Intron (SNP) | VAF 91/164 reads (55%) | called by muse, mutect2, varscan2
- BBS4 | c.*675C>G | 3'UTR (SNP) | VAF 38/118 reads (32%) | called by muse, mutect2, varscan2
- CASP10 | c.685-3272T>A | Intron (SNP) | VAF 40/219 reads (18%) | called by muse, mutect2
- CASP10 | c.685-3270T>A | Intron (SNP) | VAF 42/225 reads (19%) | called by muse, mutect2
- COPS9 | chr2:240136336 C>T | 5'Flank (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- DDR1 | c.*793del | 3'UTR (DEL) | VAF 37/86 reads (43%) | called by mutect2, pindel, varscan2
- DRD2 | c.*10C>T | 3'UTR (SNP) | VAF 62/131 reads (47%) | called by muse, mutect2, varscan2
- DZIP1L | c.2142+85del | Intron (DEL) | VAF 36/98 reads (37%) | called by mutect2, pindel, varscan2
- EZH2 | c.247-4159C>T | Intron (SNP) | VAF 76/322 reads (24%) | called by muse, mutect2, varscan2
- GDI1 | c.992-9T>C | Intron (SNP) | VAF 19/101 reads (19%) | called by muse, mutect2, varscan2
- GOLGA3 | c.3267+14A>G | Intron (SNP) | VAF 35/129 reads (27%) | catalogued as rs888843397; called by muse, mutect2, varscan2
- KCTD1 | c.-15-45976G>A | Intron (SNP) | VAF 44/122 reads (36%) | called by muse, mutect2, varscan2
- LILRB1 | c.1800+355C>A | Intron (SNP) | VAF 76/92 reads (83%) | called by muse, mutect2, varscan2
- MIR6511A3 | chr16:16372493 G>T | 3'Flank (SNP) | VAF 25/33 reads (76%) | called by mutect2, varscan2
- MXD4 | c.165-987A>T | Intron (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- OBSCN | chr1:228204146 T>C | 5'Flank (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- OR6W1P | n.726T>C | RNA (SNP) | VAF 44/105 reads (42%) | called by muse, mutect2, varscan2
- PDE4C | c.-209-117G>C | Intron (SNP) | VAF 4/35 reads (11%) | called by muse, varscan2
- PHF2 | c.*1615G>T | 3'UTR (SNP) | VAF 26/150 reads (17%) | catalogued as rs943096996; called by muse, mutect2, varscan2
- PTPN6 | c.9-36G>T | Intron (SNP) | VAF 94/116 reads (81%) | called by muse, mutect2, varscan2
- RBFOX3 | c.*12G>T | 3'UTR (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- SMOC2 | c.1323+666T>C | Intron (SNP) | VAF 44/160 reads (28%) | catalogued as rs768681567; called by muse, mutect2, varscan2
- SYNE3 | c.*8394A>T | 3'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- TAT | c.236-45del | Intron (DEL) | VAF 101/421 reads (24%) | called by mutect2, pindel, varscan2
- TMEM135 | c.*4624C>T | 3'UTR (SNP) | VAF 91/353 reads (26%) | called by muse, mutect2, varscan2
- TNFAIP8 | c.-44A>G | 5'UTR (SNP) | VAF 30/104 reads (29%) | called by muse, mutect2, varscan2
- TP53TG3D | c.*182G>T | 3'UTR (SNP) | VAF 215/455 reads (47%) | called by muse, mutect2, varscan2
- TPO | c.2387-154G>A | Intron (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- TRIM39 | c.1010-303A>C | Intron (SNP) | VAF 60/144 reads (42%) | called by muse, mutect2, varscan2
- TTN | c.4815-37C>G | Intron (SNP) | VAF 151/293 reads (52%) | called by muse, mutect2, varscan2
- TTN | c.4815-38C>A | Intron (SNP) | VAF 151/298 reads (51%) | catalogued as COSV100630261; called by muse, mutect2, varscan2
- WT1 | chr11:32437934 G>T | 5'Flank (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
